Somatic mutation profile of tumor specimen TARGET-30-PATMFL-01A (aliquot TARGET-30-PATMFL-01A-01D) from TARGET case TARGET-30-PATMFL, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 8.3 years (3,020 days).
Specimen TARGET-30-PATMFL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 866142d0-17ac-4093-b695-28712acc2702.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATMFL-10A (Blood Derived Normal), aliquot TARGET-30-PATMFL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fab6ee0-c5f2-4082-aa4e-4b2eabf4936a

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>A p.F1174L | Missense Mutation (SNP) | VAF 38/100 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AXL | c.1747C>A p.L583M (on ENST00000301178 / NM_021913.5; = p.L574M on NM_001699.6) | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56563576; called by muse, mutect2, varscan2
- ELF4 | c.1545G>T p.Q515H | Missense Mutation (SNP) | VAF 30/31 reads (97%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as COSV57451335; called by muse, mutect2, varscan2
- TRPS1 | chr8:115408959 C>A | 3'Flank (SNP) | VAF 9/183 reads (5%) | called by muse, mutect2
